Surgical pathology report (de-identified scan), TCGA case TCGA-IE-A4EH, project TCGA-SARC (Sarcoma), tissue source site ABS - IUPUI, specimen TCGA-IE-A4EH-01A (Primary Tumor).

[page 1 of 2]
Operative Procedure:
DA Vinci hysterectomy

Specimen Received:
Uterus and cervix

Final Pathologic Diagnosis:

Uterus and cervix, da Vinci hysterectomy:

Leiomyosarcoma, high-grade, 4.9 cm.

Surgical margins are negative for malignancy and dysplasia.

Uterine cervix, with focal squamous carcinoma in situ (CIS/CIN 3) from 6-9

o' clock.

Surgical margins are negative for leiomyosarcoma and squamous dysplasia.

See synoptic report.

ICD-0-3

leiomyosarcoma, nos 8890/3

Site: corpus uteri c54.9

lw
10/23/12

Sarcoma synoptic report

Procedure: Robotic hysterectomy

Tumor site: Uterine corpus

Tumor size: 4.9 cm (greatest dimension)

Macroscopic extent of tumor: Tumor is limited to the uterine corpus

Histologic type: Leiomyosarcoma

Mitotic rate: 16/10 high-power fields (HPF)

Necrosis: Present (Extent: less than 50%)

Histologic grade: High-grade,
(grade 2 of 3,

Sarcoma Group, FNCLCC)

Margins: Margins negative for sarcoma

At least 2.5 cm from nearest surgical margin (paracervical)

Pathologic staging (pTNM)

TNM descriptors: None known

Primary tumor (pT): pT1a

Regional lymph nodes (pN): Not examined, pNX

Distant metastasis (pM): Not assessable

Additional pathologic findings: None

~~Ancillary studies~~

Immunohistochemistry: Not performed

Cytogenetics: Not performed

Molecular Pathology: Not performed

Radiographic findings: Not known

Preresection treatment: Not known

Treatment effect: Not applicable

The examination of this case material and the preparation of this report were performed by the staff pathologist.

[page 2 of 2]
Gross Description:

Received is a single formalin filled container labeled with the patient's name, and "uterus and cervix." The specimen consists of a hysterectomy specimen including a uterus (11 x 9.8 x 7.2 cm) and attached cervix. The uterus has been previously incised and the parametrial soft tissue is inked in blue. The serosa is pink-tan, smooth and glistening with no apparent abnormalities. The ectocervix is pink-tan with a smooth and glistening mucosa and has dimensions of 2.7 x 2 cm. The external os is slit like with a diameter of 1.1 cm. The endocervix, which has a length of 2.1 cm, has a pink-tan mucosa with the normal palmate folds. The endometrial cavity (3.2 cm cornu to cornu, 5.4 cm from fundus to lower uterine segment) is pink-tan and focally hemorrhagic with a thickness averaging 0.2 cm. The myometrium is remarkable for a 4.9 x 4.8 x 4.5 cm solitary, exophytic mass on the anterior aspect of the uterus that comes to within 2.5 cm of the lower uterine segment. The cut surface is tan-white, fleshy and variegated with focal areas of hemorrhage and necrosis. The remaining myometrium is unremarkable and is pink-tan, finely trabeculated with a greatest thickness of 2.8 cm.

Representative sections are submitted as follows:

- 1-2 12 to 3 o' clock cervix;
- 3-6 3 to 6 o' clock cervix;
- 7-9 6 to 9 o' clock cervix;
- 10-12 9 to 12 o' clock cervix;
- 13 anterior lower uterine segment;
- 14 posterior lower uterine segment;
- 15 mass to show greatest depth of invasion;
- 16-17 mass to serosa;
- 18-19 representative sections of mass;
- 20 anterior endomyometrium, full thickness;
- 21 posterior endomyometrium, full thickness.

Microscopic Description:

The final diagnosis of each specimen incorporates the microscopic examination findings.

END OF REPORT

Taken: DOB:) Gender: F

H/E-PA Discrepancy		
Prior Neoplasia History		

10/23/12

Source: NCI Genomic Data Commons file 06bc610d-e540-4bf8-b198-00003711a84a (TCGA-IE-A4EH.4653AA00-DE0D-483C-AD4C-F281A9F015F7.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).